Gene-level copy-number profile of tumor specimen C3N-02700-01 from CPTAC case C3N-02700, project CPTAC-3 (Lip — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lip, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 80.8 years (29,529 days).
Specimen C3N-02700-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lip; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cbd26510-89d5-42aa-9341-86e638930ac3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02700-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/e9512070-9ff1-4745-8456-e8e9cf38ed9e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 4; copy number 2: 6,487; copy number 3: 2,928; copy number 4: 45,865; copy number 5: 1,094; copy number 6: 1,121; copy number 7: 345; copy number 8: 347; copy number 9: 46; copy number 10: 15; copy number 11: 62; copy number 12: 11; copy number 13: 34; copy number 16: 38.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–140,992,659, 1 gene (within-gene range 0–2): Y_RNA.
- chr21:37,337,382–37,366,858, 1 gene (within-gene range 0–2): AP001437.2.
- chr21:37,365,573–37,526,358, 1 gene (within-gene range 0–2): DYRK1A.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 206 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:137,715,332–137,715,440, 1 gene, copy number 9: Y_RNA.
- chr2:139,366,165–140,221,485, 11 genes, copy number 12: AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27.
- chr5:58,198–2,835,139, 82 genes, copy number 10–16 (broad region; genes not listed).
- chr5:32,354,350–34,373,850, 33 genes, copy number 10–13: ZFR, MIR579, AC074134.1, SUB1, LINC02061, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160, AC034231.1, TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1, AC138853.1.
- chr5:36,192,589–36,725,195, 9 genes, copy number 11: NADK2, NADK2-AS1, RANBP3L, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3.
- chr5:41,306,952–45,895,970, 70 genes, copy number 9–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
